Somatic mutation profile of tumor specimen TCGA-23-1117-01A (aliquot TCGA-23-1117-01A-02W-0486-08) from TCGA case TCGA-23-1117, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 43.0 years (15,690 days).
Specimen TCGA-23-1117-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 38d93887-2944-4384-8687-58a0a484d0f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1117-10A (Blood Derived Normal), aliquot TCGA-23-1117-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cbe103f-e708-4b97-815d-3a317101685f

The open-access MAF lists 136 somatic variants for this specimen: 101 protein-altering or splice-affecting, 30 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 30, Nonsense Mutation 6, Frame Shift Del 4, In Frame Del 3, Intron 3, Splice Site 3, Splice Region 1, 3'Flank 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs864321715, CM161051, COSV59247929; ClinVar: pathogenic; called by muse, mutect2, varscan2
- USH2A | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 120/211 reads (57%) | catalogued as rs111033334, CM071124, COSV56408694; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAMP | c.760A>T p.K254* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV50308909; called by muse, mutect2, varscan2
- AGXT2 | c.545G>C p.R182T | Missense Mutation (SNP) | VAF 102/531 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51488924; called by muse, mutect2, varscan2
- ANPEP | c.428G>C p.G143A | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV100262571; called by muse, mutect2, varscan2
- AOC3 | c.1301A>T p.Q434L | Missense Mutation (SNP) | VAF 76/104 reads (73%) | SIFT tolerated (0.05); PolyPhen benign (0.187); catalogued as COSV53828055; called by muse, mutect2, varscan2
- ARHGEF15 | c.160C>G p.P54A | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.01); catalogued as rs1421216121, COSV62725918; called by muse, mutect2, varscan2
- ATP2B3 | c.3646G>A p.V1216M | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1557022577, COSV54856172; called by muse, mutect2, varscan2
- BACE1 | c.1256C>G p.A419G | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV56120292; called by muse, mutect2, varscan2
- C4BPB | c.485G>T p.S162I | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV54692207; called by muse, mutect2, varscan2
- C6orf15 | c.488C>A p.S163* | Nonsense Mutation (SNP) | VAF 8/156 reads (5%) | catalogued as COSV52540669; called by muse, mutect2
- CCDC69 | c.163C>G p.R55G | Missense Mutation (SNP) | VAF 35/255 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV62599402, COSV62600429; called by muse, mutect2, varscan2
- CCDC7 | c.2527C>T p.Q843* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as rs1462957448, COSV56548750; called by muse, mutect2, varscan2
- CDC6 | c.1335G>T p.R445S | Missense Mutation (SNP) | VAF 255/320 reads (80%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV52931094; called by muse, mutect2, varscan2
- CEP57L1 | c.1016+1G>A p.X339_splice | Splice Site (SNP) | VAF 17/165 reads (10%) | catalogued as COSV61245587; called by muse, mutect2, varscan2
- CNGB1 | c.522dup p.K175Qfs*4 | Frame Shift Ins (INS) | VAF 8/72 reads (11%) | catalogued as rs1277141710, COSV99209762; called by mutect2, pindel
- COL15A1 | c.2758A>C p.K920Q | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV66647862; called by muse, mutect2, varscan2
- COL4A4 | c.2083G>T p.G695C | Missense Mutation (SNP) | VAF 81/122 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61634752; called by muse, mutect2, varscan2
- COL4A5 | c.3325C>A p.P1109T | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV100086384; called by muse, mutect2
- DCLK2 | c.1780G>A p.E594K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.166); catalogued as rs1332687423, COSV56209079; called by muse, varscan2
- DIPK2A | c.688G>C p.A230P | Missense Mutation (SNP) | VAF 195/453 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.102); catalogued as COSV59857195, COSV59858050; called by muse, mutect2, varscan2
- DSG3 | c.2621C>A p.S874Y | Missense Mutation (SNP) | VAF 97/181 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV57128332; called by muse, mutect2, varscan2
- EAPP | c.464G>C p.R155T | Missense Mutation (SNP) | VAF 100/154 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV51652729; called by muse, mutect2, varscan2
- ETS2 | c.1066G>T p.G356C | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV62873759; called by muse, mutect2, varscan2
- EXOSC2 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 69/406 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV64910759; called by muse, mutect2, varscan2
- FBLN2 | c.3302C>A p.A1101E | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV55488748; called by muse, mutect2, varscan2
- FBXO34 | c.1960T>A p.Y654N | Missense Mutation (SNP) | VAF 125/225 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58256095; called by muse, mutect2, varscan2
- FBXW10 | c.1122G>C p.K374N | Missense Mutation (SNP) | VAF 473/721 reads (66%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV57320347; called by muse, mutect2, varscan2
- GFOD1 | c.622C>A p.H208N | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV101014921; called by muse, mutect2
- GLI2 | c.4505G>A p.G1502D (on ENST00000361492 / NM_001374353.1; = p.G1519D on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs745550412, COSV58047780; called by muse, mutect2, varscan2
- H2AX | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); catalogued as COSV99597801; called by muse, mutect2, varscan2
- HMCN1 | c.15493G>T p.D5165Y | Missense Mutation (SNP) | VAF 169/535 reads (32%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.913); catalogued as COSV54924652; called by muse, mutect2, varscan2
- HOXA7 | c.531G>C p.W177C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99636209; called by muse, mutect2, varscan2
- IL1RAPL1 | c.935A>C p.E312A | Missense Mutation (SNP) | VAF 55/636 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56284928; called by muse, mutect2
- KCNA10 | c.115G>C p.G39R | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.49); catalogued as COSV63905090; called by muse, mutect2, varscan2
- KCNA3 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as COSV63902053; called by muse, mutect2, varscan2
- KCNH3 | c.3218T>A p.V1073D | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.72); catalogued as COSV99234674; called by muse, mutect2, varscan2
- LCOR | c.772G>C p.V258L | Missense Mutation (SNP) | VAF 80/118 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV63631812; called by muse, mutect2, varscan2
- LGALS4 | c.604C>A p.L202I | Missense Mutation (SNP) | VAF 32/572 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100313076; called by muse, mutect2
- LVRN | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 166/469 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV63497939; called by muse, mutect2, varscan2
- MAPKAPK2 | c.564G>A p.K188= | Splice Region (SNP) | VAF 46/348 reads (13%) | catalogued as COSV99685713; called by muse, mutect2, varscan2
- MARCHF2 | c.245G>C p.C82S | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.393); catalogued as COSV53105470, COSV53106173; called by muse, mutect2, varscan2
- MAST2 | c.3574G>T p.E1192* | Nonsense Mutation (SNP) | VAF 7/135 reads (5%) | catalogued as COSV100787809; called by muse, mutect2
- MS4A2 | c.713T>C p.M238T | Missense Mutation (SNP) | VAF 69/286 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370005134, COSV54013371; called by muse, mutect2, varscan2
- MTTP | c.2615A>T p.Q872L | Missense Mutation (SNP) | VAF 152/386 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55508554; called by muse, mutect2, varscan2
- NUP54 | c.1029G>A p.M343I | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as COSV53576733; called by muse, mutect2, varscan2
- PASD1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 314/1529 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1432580716, COSV64856765; called by muse, mutect2, varscan2
- PCYT2 | c.132G>T p.Q44H | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100155401; called by muse, mutect2, varscan2
- PIKFYVE | c.4588C>G p.L1530V | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV52246168; called by muse, mutect2, varscan2
- PLEKHA5 | c.3115C>G p.Q1039E | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1565671138, COSV54708284; called by muse, mutect2, varscan2
- PNMA5 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.108); catalogued as COSV100721571; called by muse, mutect2, varscan2
- PPP1R10 | c.981C>A p.S327R | Missense Mutation (SNP) | VAF 185/348 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as COSV64740039; called by muse, mutect2, varscan2
- PRAMEF20 | c.140G>C p.R47T | Missense Mutation (SNP) | VAF 150/328 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV57081043; called by muse, mutect2, varscan2
- PRICKLE2 | c.2038C>A p.L680I (on ENST00000295902; = p.L624I on NM_198859.4) | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.995); catalogued as COSV55769947; called by muse, mutect2, varscan2
- PRPF40A | c.367C>G p.P123A | Missense Mutation (SNP) | VAF 61/79 reads (77%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as COSV58443645; called by muse, mutect2, varscan2
- PSEN2 | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); catalogued as rs1434992855, COSV100422790; called by muse, mutect2, varscan2
- RASGRF1 | c.760G>C p.E254Q | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV69181679; called by muse, mutect2, varscan2
- RNASEL | c.664A>T p.T222S | Missense Mutation (SNP) | VAF 184/401 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.04); catalogued as COSV62377524; called by muse, mutect2, varscan2
- RNF20 | c.1094T>G p.V365G | Missense Mutation (SNP) | VAF 87/557 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV66661937; called by muse, mutect2, varscan2
- RTN4 | c.3014-2A>G p.X1005_splice (on ENST00000337526 / NM_020532.5; = p.X12_splice on NM_007008.3) | Splice Site (SNP) | VAF 7/31 reads (23%) | catalogued as COSV58271689; called by muse, mutect2
- RYR1 | c.14A>T p.E5V | Missense Mutation (SNP) | VAF 37/336 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV62105021; called by muse, mutect2, varscan2
- SCEL | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV62994175; called by muse, mutect2, varscan2
- SDK2 | c.5092G>T p.V1698F | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.393); catalogued as COSV66192504; called by muse, mutect2, varscan2
- SEMA6A | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 45/416 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV57315325; called by muse, mutect2
- SERPINB11 | c.1118T>A p.F373Y | Missense Mutation (SNP) | VAF 750/1144 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV66957431, COSV66957524; called by muse, mutect2, varscan2
- SLAMF9 | c.470C>A p.S157Y | Missense Mutation (SNP) | VAF 102/300 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV100928168, COSV63637040; called by muse, mutect2, varscan2
- SLC24A2 | c.1462C>A p.P488T | Missense Mutation (SNP) | VAF 172/238 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53870003, COSV53871202; called by muse, varscan2
- SLC25A32 | c.303C>A p.F101L | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV52568651; called by muse, mutect2
- SMTNL1 | c.1285G>T p.V429L (on ENST00000399154; = p.V466L on NM_001105565.2) | Missense Mutation (SNP) | VAF 13/137 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.431); catalogued as COSV54702457; called by muse, mutect2
- SMYD5 | c.209G>A p.C70Y | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99242684; called by muse, mutect2
- TARDBP | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as rs1358405889, COSV53570753; called by muse, mutect2, varscan2
- TBC1D16 | c.1535G>T p.S512I | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV100187690; called by mutect2, varscan2
- TCF4 | c.1972G>T p.G658* | Nonsense Mutation (SNP) | VAF 31/131 reads (24%) | catalogued as rs1555707632, COSV61902607; called by muse, mutect2, varscan2
- TMEM209 | c.880G>C p.A294P | Missense Mutation (SNP) | VAF 12/399 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100390283; called by muse, mutect2
- TMEM94 | c.1012A>C p.T338P | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); catalogued as COSV100049971; called by muse, varscan2
- TMOD4 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 314/1207 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV54860816; called by muse, mutect2, varscan2
- TRMT12 | c.1040T>C p.L347P | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100149073; called by muse, mutect2
- TRPC3 | c.2348T>C p.V783A (on ENST00000379645 / NM_001366479.2; = p.V710A on NM_003305.2) | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs1386284134, COSV53378766; called by muse, mutect2, varscan2
- TSGA13 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 34/386 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.215); catalogued as COSV58406327; called by muse, mutect2
- TTN | c.4674T>G p.F1558L (on ENST00000591111; = p.F1512L on NM_003319.4) | Missense Mutation (SNP) | VAF 12/128 reads (9%) | PolyPhen benign (0.179); catalogued as COSV59979375; called by muse, mutect2
- UIMC1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs779796802, COSV65893244; called by mutect2, varscan2
- VSIR | c.520G>C p.A174P | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV56479880; called by muse, mutect2, varscan2
- WNK1 | c.4052C>T p.A1351V (on ENST00000315939 / NM_018979.4; = p.A1104V on NM_014823.3) | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV60041155; called by muse, mutect2, varscan2
- YTHDF2 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370101470; called by muse, mutect2, varscan2
- ZNF341 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.241); catalogued as rs1468849894, COSV100677641; called by muse, mutect2, varscan2
- ZNF461 | c.1100G>T p.R367M | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.843); catalogued as COSV64454570; called by muse, mutect2, varscan2
- ZNF496 | c.1030G>C p.E344Q | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs774017482, COSV54180391, COSV99665722; called by muse, mutect2, varscan2
- ZNF691 | c.136G>A p.E46K (on ENST00000372502; = p.E15K on NM_015911.3) | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV65289556; called by muse, mutect2, varscan2
- ZNF91 | c.3152A>G p.K1051R | Missense Mutation (SNP) | VAF 5/115 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1450649258, COSV100322099, COSV56081234; called by muse, mutect2
- ZSCAN20 | c.326C>A p.T109N | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.48); PolyPhen benign (0.129); catalogued as COSV63683889; called by muse, mutect2, varscan2
- ZSCAN20 | c.1816G>T p.V606L | Missense Mutation (SNP) | VAF 30/901 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV100792477; called by muse, mutect2
- AOC1 | c.167_182del p.L56Pfs*23 | Frame Shift Del (DEL) | VAF 10/114 reads (9%) | called by mutect2, pindel
- FBLN2 | c.1549-19_1559del p.X517_splice | Splice Site (DEL) | VAF 8/60 reads (13%) | called by mutect2, pindel
- HBS1L | c.872_900del p.T291Kfs*15 | Frame Shift Del (DEL) | VAF 269/728 reads (37%) | called by mutect2, pindel
- HORMAD1 | c.776_784del p.V259_D261del | In Frame Del (DEL) | VAF 22/238 reads (9%) | called by mutect2, pindel
- IGHV4-61 | c.170G>C p.W57S | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.762); called by muse, mutect2
- PRAMEF20 | c.1055A>T p.E352V | Missense Mutation (SNP) | VAF 480/1930 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.263); called by muse, mutect2, varscan2
- THSD7A | c.3284_3316del p.N1095_S1105del | In Frame Del (DEL) | VAF 152/782 reads (19%) | called by mutect2, pindel
- TOP2A | c.613del p.E205Nfs*34 | Frame Shift Del (DEL) | VAF 282/1396 reads (20%) | called by pindel, varscan2
- TOP2A | c.597_605del p.R200_G202del | In Frame Del (DEL) | VAF 296/1326 reads (22%) | called by pindel, varscan2
- TP53 | c.430_460del p.Q144Afs*16 | Frame Shift Del (DEL) | VAF 74/137 reads (54%) | called by mutect2, pindel
- ACAN | c.252A>G p.V84= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV61365910; called by muse, mutect2, varscan2
- ANPEP | c.429A>G p.G143= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV55593522; called by muse, mutect2, varscan2
- CCDC33 | c.1491G>A p.L497= | Silent (SNP) | VAF 38/162 reads (23%) | catalogued as rs778477758, COSV51502190; called by muse, mutect2, varscan2
- CDC6 | c.336A>C p.L112= | Silent (SNP) | VAF 61/151 reads (40%) | catalogued as COSV52931088; called by muse, mutect2, varscan2
- CDH8 | c.1167G>T p.P389= | Silent (SNP) | VAF 88/218 reads (40%) | catalogued as COSV54854562, COSV54886658; called by muse, mutect2, varscan2
- CUX1 | c.1806T>G p.R602= | Silent (SNP) | VAF 22/44 reads (50%) | catalogued as COSV52909296; called by muse, mutect2, varscan2
- DGKA | c.942G>A p.A314= | Silent (SNP) | VAF 129/226 reads (57%) | catalogued as COSV59387716; called by muse, mutect2, varscan2
- EML4 | c.1236T>A p.V412= | Silent (SNP) | VAF 163/280 reads (58%) | catalogued as COSV59302502; called by muse, mutect2, varscan2
- FAM153B | c.312A>T p.T104= (on ENST00000253490; = p.T27= on NM_001265615.1) | Silent (SNP) | VAF 74/819 reads (9%) | catalogued as COSV53687682; called by muse, mutect2, varscan2
- H2BC5 | c.354C>G p.A118= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as rs541069056, COSV56801111, COSV56802787; called by muse, mutect2, varscan2
- IRAG1 | c.486G>A p.A162= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as rs753874354, COSV70212391; called by muse, mutect2, varscan2
- IZUMO1 | c.729C>G p.A243= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV55807031, COSV99710557; called by muse, mutect2
- KRT40 | c.102C>T p.L34= | Silent (SNP) | VAF 13/176 reads (7%) | catalogued as rs376601595, COSV66696396; called by muse, mutect2
- KRT5 | c.688C>T p.L230= | Silent (SNP) | VAF 19/412 reads (5%) | catalogued as COSV99357776; called by muse, mutect2
- MSH2 | c.1227G>A p.Q409= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as rs759098126, COSV51882569; called by muse, mutect2, varscan2
- OR51T1 | c.747A>C p.A249= | Silent (SNP) | VAF 144/227 reads (63%) | catalogued as rs1442921225, COSV59027109; called by muse, mutect2, varscan2
- OR5M1 | c.582C>G p.V194= | Silent (SNP) | VAF 55/200 reads (28%) | catalogued as COSV73202310; called by muse, mutect2, varscan2
- OR6X1 | c.237G>A p.L79= | Silent (SNP) | VAF 80/188 reads (43%) | catalogued as COSV60010228; called by muse, mutect2, varscan2
- OSBPL7 | c.711G>A p.V237= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV99136517; called by muse, mutect2
- PCDHGB4 | c.1440G>T p.G480= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV53999456; called by muse, varscan2
- RIMS1 | c.2967T>C p.S989= | Silent (SNP) | VAF 41/262 reads (16%) | catalogued as COSV53472693; called by muse, mutect2, varscan2
- RPN2 | c.1701C>T p.V567= | Silent (SNP) | VAF 110/343 reads (32%) | catalogued as rs757241492, COSV52907759; called by muse, mutect2, varscan2
- SIPA1L3 | c.2607G>A p.G869= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV55920758; called by muse, mutect2, varscan2
- SOS2 | c.3600G>T p.L1200= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV53571723; called by muse, mutect2, varscan2
- SPATA5L1 | c.2184G>A p.P728= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as rs773984786, COSV59745333; called by muse, mutect2, varscan2
- SPG11 | c.337C>T p.L113= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as rs878855128, COSV55999658; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYT9 | c.1437G>A p.K479= | Silent (SNP) | VAF 188/251 reads (75%) | catalogued as COSV59622722; called by muse, mutect2, varscan2
- TMEM132D | c.801C>T p.I267= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs907461232, COSV101400002, COSV70594780; called by muse, mutect2, varscan2
- UBE2E3 | c.66G>T p.A22= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV66585836; called by muse, mutect2, varscan2
- VWF | c.1599C>T p.D533= | Silent (SNP) | VAF 32/49 reads (65%) | catalogued as COSV54629257; called by muse, mutect2, varscan2
- GHRH | c.-2G>C | 5'UTR (SNP) | VAF 41/72 reads (57%) | catalogued as COSV99411090; called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442744 del AAAGAAGGAATAT | 3'Flank (DEL) | VAF 23/81 reads (28%) | called by mutect2, pindel, varscan2
- NRG1 | c.502+31233G>T | Intron (SNP) | VAF 105/204 reads (51%) | catalogued as COSV55170015; called by muse, mutect2, varscan2
- RAB3GAP2 | c.811+1619G>C | Intron (SNP) | VAF 7/26 reads (27%) | catalogued as COSV52966661; called by muse, mutect2, varscan2
- SCAI | c.99-10019A>T | Intron (SNP) | VAF 46/164 reads (28%) | catalogued as COSV60615858; called by muse, mutect2, varscan2
